Surgical pathology report (de-identified scan), TCGA case TCGA-HT-8111, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-8111-01A (Primary Tumor).

Tumor: [REDACTED]
Normal: [REDACTED]

Addendum Diagnosis:

Anaplastic Oligoastrocytoma, Astrocytoma Predominant
MIB-1 Labeling Index= 9.2%

Addendum Discussion:

Numerous MIB-1 reactive cells are present throughout the tumor. In the most proliferative areas, a labeling index of 9.2% is calculated, consistent with the anaplastic histologic features.

Microscopic Description:

Review of frozen section and permanent material demonstrate a moderately hypercellular glial neoplasm with variable and focally marked cytologic atypia. Numerous gemistocytic cells and fibrillary astrocytes are present as well as areas of prominent perivascular lymphocytic cuffing. Minor foci of classic oligodendroglioma are seen. Scattered mitotic figures are identified.

Source: NCI Genomic Data Commons file b90b28b1-5ca6-4e54-afe5-1501fa693eea (TCGA-HT-8111.9DE92BA0-F9D6-4F7B-8A92-548082B49288.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).